Somatic mutation profile of tumor specimen TARGET-10-PARILG-09A (aliquot TARGET-10-PARILG-09A-01D) from TARGET case TARGET-10-PARILG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,134 days).
Specimen TARGET-10-PARILG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4468944b-5d52-4b85-aebb-70a598681ffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARILG-14A (Bone Marrow Normal), aliquot TARGET-10-PARILG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e9af5fd-2c37-46e3-9ff0-b4928476ae64

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 2, Splice Region 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 60/142 reads (42%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- CDH5 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as rs147523967; called by muse, mutect2, varscan2
- CDON | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 131/305 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs551721918, COSV54996503; called by muse, mutect2, varscan2
- CTNND2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as COSV58902791; called by muse, mutect2, varscan2
- GATA3 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV100650867, COSV60520051; called by muse, mutect2, varscan2
- PRKN | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs746215864, COSV58261108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STAB1 | c.7291-6C>T | Splice Region (SNP) | VAF 40/100 reads (40%) | catalogued as rs1365065046; called by muse, mutect2, varscan2
- ZCWPW1 | c.1868G>T p.R623I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.201); catalogued as COSV52199410; called by muse, varscan2
- ZFHX4 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as rs780029176, COSV51491373; called by muse, mutect2, varscan2
- ZMAT3 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139328684, COSV60993012; called by muse, mutect2, varscan2
- EEF1AKNMT | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EXPH5 | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2
- KCMF1 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- LAS1L | c.2139C>G p.N713K | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MED12 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MTMR10 | c.1073T>C p.F358S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ALKBH2 | c.624C>T p.S208= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs1566113939, COSV99980399; called by muse, mutect2, varscan2
- C11orf53 | c.390C>A p.G130= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- CSMD3 | c.5208T>C p.Y1736= (on ENST00000297405 / NM_001363185.1; = p.Y1632= on NM_052900.3) | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- EP300 | c.6756G>A p.E2252= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV54339311; called by muse, mutect2, varscan2
- MUC5AC | c.14409C>T p.L4803= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs377250708; called by muse, varscan2
- KLF6 | c.676+148G>T | Intron (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99434965; called by muse, mutect2
- LYVE1 | c.258-46G>T | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- OTUB1 | c.-209C>A | 5'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
